Gene-level copy-number profile of specimen HCM-SANG-0303-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0303-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0303-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 152f1141-76ab-4b2e-9ec8-37ba6fd02806.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0303-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/e9a9404b-4112-4604-9f2c-662f7c3f2d3c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 507; copy number 1: 326; copy number 2: 35,454; copy number 3: 14,032; copy number 4: 7,586; copy number 5: 73; copy number 6: 58; copy number 7: 869; copy number 9: 1; copy number 10: 2; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,690,225–60,690,719, 1 gene (within-gene range 0–1): PPIAP70.
- chr4:49,588,772–49,589,529, 1 gene: SNX18P25.
- chr4:91,319,034–91,325,306, 1 gene (within-gene range 0–2): AC074124.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,006 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,118,534–87,222,488, 4 genes, copy number 5: ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1.
- chr2:89,252,211–91,767,701, 62 genes, copy number 5–6 (broad region; genes not listed).
- chr3:41,162,287–41,962,130, 5 genes, copy number 10–11 (within-gene range 2–11): AC009743.1, MRPS31P1, CTNNB1, ULK4, AC099537.1.
- chr10:31,602,862–33,917,804, 41 genes, copy number 5: AL161935.1, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629.
- chr11:97,222,644–97,259,987, 1 gene, copy number 5: LINC02553.
- chr13:45,341,345–45,417,975, 1 gene, copy number 5 (within-gene range 3–5): TPT1-AS1.
- chr13:45,390,353–45,436,660, 4 genes, copy number 5: RCN1P2, SLC25A30, SLC25A30-AS1, PPIAP25.
- chr19:48,755,524–49,015,970, 18 genes, copy number 5: FGF21, RNU6-317P, BCAT2, AC026803.3, HSD17B14, PLEKHA4, PPP1R15A, TULP2, NUCB1, NUCB1-AS1, AC026803.1, DHDH, BAX, AC026803.2, FTL, GYS1, RUVBL2, MIR6798.
- chr20:30,214,765–64,327,972, 870 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 278. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
